Gene-level copy-number profile of tumor specimen TCGA-56-5897-01A from TCGA case TCGA-56-5897, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 74.2 years (27,118 days).
Specimen TCGA-56-5897-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.d9fb185d-37a2-4bba-a450-9d30bd58fd79.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-56-5897-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e9c163b0-67a2-43c8-bfe0-302947ac6f31

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 137; copy number 2: 10,619; copy number 3: 17,045; copy number 4: 24,781; copy number 5: 1,652; copy number 6: 2,555; copy number 7: 2,742; copy number 8: 57; copy number 9: 216.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-56-5897-01A-11D-1631-01): tumor purity 0.32, ploidy 1.86, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 216 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:101,561,868–117,997,592, 216 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 102. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
